Gene-level copy-number profile of tumor specimen TCGA-XE-AANM-01A from TCGA case TCGA-XE-AANM, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 44.0 years (16,058 days).
Specimen TCGA-XE-AANM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 07f228d5-629a-4431-a68a-ddc56b205b2d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AANM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/7050254a-b079-4327-99fe-699f889952f3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 776; copy number 2: 13,071; copy number 3: 30,493; copy number 4: 8,696; copy number 5: 524; copy number 6: 4,450; copy number 7: 17; copy number 8: 1; copy number 10: 817; copy number 11: 14; copy number 15: 8.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:86,968,432–87,971,930, 38 genes (within-gene range 0–3): ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 857 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,474,973–13,825,079, 8 genes, copy number 15: LRRC38, AL354712.1, BRWD1P1, PDPN, RNA5SP41, AL359771.1, AL359771.2, PRDM2.
- chr1:14,124,233–14,124,335, 1 gene, copy number 8: RNU6-1265P.
- chr7:76,201,896–76,650,897, 17 genes, copy number 7: SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1, POMZP3, AC004980.2.
- chr12:66,767–34,249,958, 831 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 264. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
